MMRF case MMRF_2609 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f10d7fdd-3209-4be9-b364-911efa9cdc3a

Demographics
Sex at birth: male; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.2 years (23,814 days); ISS stage: II; Days to last known disease status: 604 days (1.7 years); Days to last follow up: 604 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 0, day 604.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Beta 2 Microglobulin 0.54 µg/mL.
- Lactate Dehydrogenase 6.08 µkat/L.
- Platelets 247 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.185 mg/dL.
- Absolute Neutrophil 1.93 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Kappa 284 mg/dL.
- Albumin 23.4 g/L.
- M Protein 3.32 g/dL.
- Creatinine 79.6 µmol/L.
- Hemoglobin 6.51 mmol/L.
- Calcium 2.15 mmol/L.

Other clinical attributes
- Day 0: Weight: 79 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2609_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2609_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
